TARGET case TARGET-30-PADKVV — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/d762fc8b-7a14-5d67-a16f-f7376e71e1c0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Age at diagnosis: 2.2 years (807 days); Year of diagnosis: 1993; Days to last follow up: 437 days (1.2 years); INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PADKVV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
